Somatic mutation profile of tumor specimen TCGA-50-5935-01A (aliquot TCGA-50-5935-01A-11D-1753-08) from TCGA case TCGA-50-5935, project TCGA-LUAD (Lung Adenocarcinoma). Sex at birth: female; Vital status: Dead; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Upper lobe, lung; AJCC pathologic stage: Stage IA; Age at diagnosis: 86.5 years (31,610 days).
Specimen TCGA-50-5935-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) f43001d4-b3f7-4cc3-a6f3-ccc7684096d8.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-50-5935-11A (Solid Tissue Normal), aliquot TCGA-50-5935-11A-01D-1753-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/800af215-08e1-4911-9976-5c50cadbffa5

The open-access MAF lists 95 somatic variants for this specimen: 73 protein-altering or splice-affecting, 18 silent, 4 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 63, Silent 18, Splice Site 4, Nonsense Mutation 3, Intron 2, Splice Region 2, In Frame Del 1, RNA 1, 3'UTR 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- EGFR | c.2236_2250del p.E746_A750del | In Frame Del (DEL) | VAF 22/67 reads (33%) | hotspot (GDC flag); catalogued as rs727504233, COSV51765066, COSV51849442; ClinVar: drug response; called by mutect2, pindel, varscan2
- AGMO | c.86C>T p.S29L | Missense Mutation (SNP) | VAF 10/136 reads (7%) | SIFT deleterious (0.03); PolyPhen benign (0.019); catalogued as COSV61120460; called by muse, mutect2
- ARFGEF1 | c.5524C>G p.Q1842E | Missense Mutation (SNP) | VAF 11/83 reads (13%) | SIFT tolerated, low confidence (0.22); PolyPhen benign (0.003); catalogued as COSV51589942; called by muse, mutect2, varscan2
- ASB2 | c.805G>C p.E269Q | Missense Mutation (SNP) | VAF 6/76 reads (8%) | SIFT tolerated (0.5); PolyPhen benign (0.026); catalogued as COSV60113776; called by muse, mutect2
- ASPM | c.1792G>C p.E598Q | Missense Mutation (SNP) | VAF 25/461 reads (5%) | SIFT tolerated (0.17); PolyPhen benign (0.045); catalogued as COSV54135434; called by muse, mutect2
- BAZ1A | c.4345G>A p.D1449N | Missense Mutation (SNP) | VAF 8/142 reads (6%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.871); catalogued as COSV62411648; called by muse, mutect2
- CDC73 | c.1491A>T p.L497F | Missense Mutation (SNP) | VAF 12/167 reads (7%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.988); catalogued as rs1448322761, COSV66469518; called by muse, mutect2
- CLSTN3 | c.1845C>A p.V615= | Splice Region (SNP) | VAF 6/31 reads (19%) | catalogued as COSV56939183; called by muse, mutect2
- CST5 | c.321C>A p.F107L | Missense Mutation (SNP) | VAF 13/116 reads (11%) | SIFT tolerated (0.14); PolyPhen benign (0.127); catalogued as COSV59015275; called by muse, mutect2, varscan2
- CXorf56 | c.378G>C p.K126N (on ENST00000536133 / NM_001170570.2; = p.K140N on NM_022101.4) | Missense Mutation (SNP) | VAF 22/294 reads (7%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.705); catalogued as COSV57438909; called by muse, mutect2
- CYYR1 | c.26G>A p.R9H | Missense Mutation (SNP) | VAF 5/47 reads (11%) | SIFT tolerated, low confidence (0.17); PolyPhen benign (0); catalogued as COSV54827898; called by muse, mutect2, varscan2
- EIF3K | c.389G>C p.G130A | Missense Mutation (SNP) | VAF 15/230 reads (7%) | SIFT tolerated (0.14); PolyPhen benign (0.033); catalogued as COSV50264432; called by muse, mutect2
- ELMOD2 | c.341G>A p.S114N | Missense Mutation (SNP) | VAF 9/88 reads (10%) | SIFT tolerated (0.64); PolyPhen benign (0); catalogued as COSV60271214; called by muse, mutect2
- EVPL | c.4551G>C p.K1517N | Missense Mutation (SNP) | VAF 6/132 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.963); catalogued as COSV56914270; called by muse, mutect2
- FAAP100 | c.1193G>T p.S398I | Missense Mutation (SNP) | VAF 14/210 reads (7%) | SIFT deleterious (0); PolyPhen possibly damaging (0.735); catalogued as COSV59886953; called by muse, mutect2
- FAM166A | c.758G>A p.R253K | Missense Mutation (SNP) | VAF 5/43 reads (12%) | SIFT deleterious (0.03); PolyPhen benign (0.003); catalogued as rs1022281614, COSV61118389; called by muse, mutect2
- FBN2 | c.4844G>A p.G1615E | Missense Mutation (SNP) | VAF 30/424 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.976); catalogued as COSV52534494; called by muse, mutect2
- FMOD | c.113A>T p.Y38F | Missense Mutation (SNP) | VAF 10/119 reads (8%) | SIFT tolerated, low confidence (0.63); PolyPhen benign (0.142); catalogued as COSV100724596; called by muse, mutect2
- FZD2 | c.683C>T p.A228V | Missense Mutation (SNP) | VAF 11/47 reads (23%) | SIFT tolerated (0.06); PolyPhen benign (0.03); catalogued as rs1169257475, COSV59528318, COSV59529385; called by muse, mutect2, varscan2
- HUWE1 | c.5509A>G p.T1837A | Missense Mutation (SNP) | VAF 12/193 reads (6%) | SIFT tolerated (0.51); PolyPhen benign (0.031); catalogued as COSV53358410; called by muse, mutect2
- IGF1 | c.441G>C p.Q147H | Missense Mutation (SNP) | VAF 20/254 reads (8%) | SIFT deleterious (0.02); PolyPhen benign (0.191); catalogued as COSV61033301, COSV61033906; called by muse, mutect2
- IKBKE | c.359-2A>G p.X120_splice | Splice Site (SNP) | VAF 22/46 reads (48%) | catalogued as COSV65626534; called by muse, mutect2, varscan2
- KIAA2026 | c.5080A>G p.I1694V | Missense Mutation (SNP) | VAF 12/104 reads (12%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs568246890, COSV67356877; called by muse, mutect2, varscan2
- KLK1 | c.329C>T p.T110I | Missense Mutation (SNP) | VAF 15/120 reads (13%) | SIFT tolerated (0.2); PolyPhen benign (0.021); catalogued as rs1475954682, COSV56827890; called by muse, mutect2, varscan2
- LAMB3 | c.3337G>A p.E1113K | Missense Mutation (SNP) | VAF 18/334 reads (5%) | SIFT tolerated (0.49); PolyPhen benign (0.001); catalogued as COSV50524499; called by muse, mutect2
- LRFN5 | c.1632C>G p.F544L | Missense Mutation (SNP) | VAF 12/304 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV53269334; called by muse, mutect2
- MAGEA8 | c.784C>T p.R262C | Missense Mutation (SNP) | VAF 16/214 reads (7%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.985); catalogued as rs929885088, COSV54063682; called by muse, mutect2
- MED13 | c.6373C>T p.Q2125* | Nonsense Mutation (SNP) | VAF 12/214 reads (6%) | catalogued as COSV67265932; called by muse, mutect2
- MUC17 | c.9872C>T p.T3291I | Missense Mutation (SNP) | VAF 38/436 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.969); catalogued as COSV60298528; called by muse, mutect2
- MYO16 | c.1918G>A p.E640K | Missense Mutation (SNP) | VAF 7/32 reads (22%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.935); catalogued as COSV51809814; called by muse, mutect2, varscan2
- NBAS | c.955-2A>T p.X319_splice | Splice Site (SNP) | VAF 8/69 reads (12%) | catalogued as COSV55732655; called by muse, mutect2, varscan2
- NRG3 | c.1656-1G>C p.X552_splice (on ENST00000404547 / NM_001370084.1; = p.X528_splice on NM_001010848.4 and 2 other RefSeq transcripts) | Splice Site (SNP) | VAF 51/285 reads (18%) | catalogued as COSV64576990; called by muse, mutect2, varscan2
- NUP98 | c.4354G>A p.A1452T (on ENST00000359171 / NM_001365126.1; = p.A1435T on NM_016320.5 and 4 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 21/220 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV61436441; called by muse, mutect2
- NXPH1 | c.57C>G p.V19= | Splice Region (SNP) | VAF 15/129 reads (12%) | catalogued as COSV68314117; called by muse, mutect2, varscan2
- OAF | c.324C>A p.H108Q | Missense Mutation (SNP) | VAF 8/164 reads (5%) | SIFT tolerated (0.13); PolyPhen benign (0.124); catalogued as COSV61109719; called by muse, mutect2
- OR10H3 | c.209C>G p.S70C | Missense Mutation (SNP) | VAF 22/272 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.977); catalogued as COSV100008464; called by muse, mutect2
- OR10J3 | c.163C>T p.H55Y | Missense Mutation (SNP) | VAF 16/310 reads (5%) | SIFT tolerated (0.07); PolyPhen benign (0.066); catalogued as COSV59954498, COSV59954984, COSV59955013; called by muse, mutect2
- OR12D2 | c.88C>T p.L30F | Missense Mutation (SNP) | VAF 20/223 reads (9%) | SIFT tolerated (0.09); PolyPhen benign (0.242); catalogued as COSV65829544; called by muse, mutect2
- OTOP3 | c.1367G>A p.R456Q | Missense Mutation (SNP) | VAF 5/38 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs149666474; called by mutect2, varscan2
- P2RX5 | c.595C>G p.P199A | Missense Mutation (SNP) | VAF 107/356 reads (30%) | SIFT deleterious (0); PolyPhen possibly damaging (0.905); catalogued as COSV56593352; called by muse, mutect2, varscan2
- PAX1 | c.1030G>T p.A344S | Missense Mutation (SNP) | VAF 12/52 reads (23%) | SIFT tolerated, low confidence (0.32); PolyPhen benign (0.03); catalogued as COSV68272875; called by muse, varscan2
- PDE3B | c.2573C>T p.A858V | Missense Mutation (SNP) | VAF 19/150 reads (13%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.999); catalogued as COSV56388235; called by muse, mutect2, varscan2
- PGBD2 | c.372G>C p.W124C | Missense Mutation (SNP) | VAF 6/144 reads (4%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.997); catalogued as COSV61400786; called by muse, mutect2
- PKD2L2 | c.389G>C p.R130T | Missense Mutation (SNP) | VAF 13/144 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.939); catalogued as COSV99296557; called by muse, mutect2
- PRB4 | c.289G>A p.G97R | Missense Mutation (SNP) | VAF 96/554 reads (17%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.01); catalogued as COSV54398968; called by muse, varscan2
- RBM7 | c.199A>G p.M67V | Missense Mutation (SNP) | VAF 8/98 reads (8%) | SIFT deleterious (0.03); PolyPhen benign (0.262); catalogued as rs1454517755, COSV57784707; called by muse, mutect2
- RICTOR | c.118G>A p.E40K | Missense Mutation (SNP) | VAF 15/199 reads (8%) | SIFT deleterious (0.01); PolyPhen benign (0.274); catalogued as COSV99705497; called by muse, mutect2
- RPS6KC1 | c.2554G>A p.D852N | Missense Mutation (SNP) | VAF 18/360 reads (5%) | SIFT deleterious (0.04); PolyPhen benign (0.227); catalogued as COSV65301794; called by muse, mutect2
- RRP15 | c.835G>A p.D279N | Missense Mutation (SNP) | VAF 6/114 reads (5%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.454); catalogued as COSV65117394; called by muse, mutect2
- RYR1 | c.10759G>A p.D3587N | Missense Mutation (SNP) | VAF 5/74 reads (7%) | SIFT tolerated (0.35); PolyPhen benign (0.003); catalogued as rs1271768189, COSV62100028; called by muse, mutect2
- SENP5 | c.542G>C p.G181A | Missense Mutation (SNP) | VAF 4/33 reads (12%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.03); catalogued as COSV100052191; called by muse, mutect2, varscan2
- SHARPIN | c.319C>G p.Q107E | Missense Mutation (SNP) | VAF 5/117 reads (4%) | SIFT tolerated (0.15); PolyPhen benign (0); catalogued as COSV59364051; called by muse, mutect2
- SIK2 | c.1402C>T p.H468Y | Missense Mutation (SNP) | VAF 7/63 reads (11%) | SIFT deleterious (0.03); PolyPhen benign (0.055); catalogued as rs772138429, COSV59254950; called by muse, mutect2
- SLC44A3 | c.1759G>C p.E587Q (on ENST00000271227 / NM_001114106.3; = p.E539Q on NM_152369.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 16/149 reads (11%) | SIFT tolerated (0.05); PolyPhen benign (0.187); catalogued as COSV54732782; called by muse, mutect2, varscan2
- SLFN13 | c.1102C>T p.Q368* | Nonsense Mutation (SNP) | VAF 9/71 reads (13%) | catalogued as COSV53193357; called by muse, mutect2, varscan2
- SLITRK4 | c.2261A>G p.D754G | Missense Mutation (SNP) | VAF 76/289 reads (26%) | SIFT deleterious (0.03); PolyPhen benign (0.01); catalogued as COSV62025464; called by muse, mutect2, varscan2
- SMARCA2 | c.4420C>G p.L1474V | Missense Mutation (SNP) | VAF 15/163 reads (9%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.985); catalogued as COSV56648123; called by muse, mutect2
- SMYD2 | c.1249G>A p.G417S | Missense Mutation (SNP) | VAF 16/192 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs778741699, COSV65290309; called by muse, mutect2
- TBXAS1 | c.236+1G>A p.X79_splice | Splice Site (SNP) | VAF 13/107 reads (12%) | catalogued as COSV54951155; called by muse, mutect2, varscan2
- TCF12 | c.233A>G p.D78G | Missense Mutation (SNP) | VAF 7/82 reads (9%) | SIFT tolerated (0.13); PolyPhen probably damaging (0.984); catalogued as COSV51016841; called by muse, mutect2
- TLR7 | c.2294C>T p.T765I | Missense Mutation (SNP) | VAF 10/198 reads (5%) | SIFT deleterious (0); PolyPhen possibly damaging (0.653); catalogued as COSV66125085; called by muse, mutect2
- TMC7 | c.1395G>C p.K465N | Missense Mutation (SNP) | VAF 10/154 reads (6%) | SIFT deleterious (0.01); PolyPhen benign (0.007); catalogued as COSV58586372; called by muse, mutect2
- TNFRSF11A | c.1441G>A p.E481K | Missense Mutation (SNP) | VAF 10/86 reads (12%) | SIFT tolerated (0.11); PolyPhen benign (0.272); catalogued as COSV54025334; called by muse, mutect2, varscan2
- TNS1 | c.2320G>A p.G774R | Missense Mutation (SNP) | VAF 7/44 reads (16%) | SIFT tolerated (0.19); PolyPhen possibly damaging (0.855); catalogued as COSV50742574; called by muse, mutect2, varscan2
- TTN | c.84147C>A p.D28049E (on ENST00000591111; = p.D20625E on NM_003319.4) | Missense Mutation (SNP) | VAF 48/169 reads (28%) | PolyPhen probably damaging (0.996); catalogued as COSV60243578; called by muse, mutect2, varscan2
- USP48 | c.2029C>T p.Q677* | Nonsense Mutation (SNP) | VAF 12/112 reads (11%) | catalogued as COSV57612950; called by muse, mutect2, varscan2
- WNK1 | c.1648G>C p.D550H | Missense Mutation (SNP) | VAF 26/385 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV60041868; called by muse, mutect2
- XAGE2 | c.41G>A p.R14K | Missense Mutation (SNP) | VAF 21/382 reads (5%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.458); catalogued as COSV53684656; called by muse, mutect2
- ZC3H4 | c.259G>A p.G87R | Missense Mutation (SNP) | VAF 24/298 reads (8%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.796); catalogued as rs1361177915, COSV53415733; called by muse, mutect2
- ZNF582 | c.1244G>C p.R415T | Missense Mutation (SNP) | VAF 8/102 reads (8%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.94); catalogued as COSV56733251; called by muse, mutect2
- ZNF652 | c.1263T>G p.D421E | Missense Mutation (SNP) | VAF 50/195 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as COSV62948265; called by muse, mutect2, varscan2
- ZNF678 | c.1393G>A p.E465K | Missense Mutation (SNP) | VAF 7/82 reads (9%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.674); catalogued as COSV59386097; called by muse, mutect2
- OR14C36 | c.583G>A p.V195I | Missense Mutation (SNP) | VAF 8/144 reads (6%) | SIFT tolerated (1); PolyPhen benign (0.009); called by muse, mutect2
- AHNAK | c.17647C>T p.L5883= | Silent (SNP) | VAF 49/246 reads (20%) | catalogued as COSV57203208, COSV57224683; called by muse, varscan2
- BDKRB2 | c.750G>T p.V250= | Silent (SNP) | VAF 5/23 reads (22%) | catalogued as COSV100021367; called by muse, mutect2
- CD2BP2 | c.819G>A p.S273= | Silent (SNP) | VAF 11/95 reads (12%) | catalogued as rs765577639, COSV59769477; called by muse, mutect2, varscan2
- DLEC1 | c.1992C>T p.F664= | Silent (SNP) | VAF 6/46 reads (13%) | catalogued as COSV57304360; called by muse, mutect2, varscan2
- EPC1 | c.1992G>A p.V664= | Silent (SNP) | VAF 11/82 reads (13%) | catalogued as COSV53928528; called by muse, mutect2, varscan2
- FAM47A | c.1188G>T p.V396= | Silent (SNP) | VAF 4/62 reads (6%) | catalogued as COSV60498925; called by muse, mutect2
- GPAA1 | c.1545C>T p.L515= | Silent (SNP) | VAF 6/72 reads (8%) | catalogued as COSV61906242; called by muse, mutect2
- IQCC | c.468C>T p.S156= | Silent (SNP) | VAF 14/118 reads (12%) | catalogued as rs1350488506, COSV52210529; called by muse, mutect2, varscan2
- MYH6 | c.3330G>C p.L1110= | Silent (SNP) | VAF 22/258 reads (9%) | catalogued as COSV100676842, COSV62453237; called by muse, mutect2
- MYO9B | c.1065C>G p.L355= | Silent (SNP) | VAF 5/85 reads (6%) | catalogued as COSV68281766; called by muse, mutect2
- NOS1 | c.1326G>A p.G442= | Silent (SNP) | VAF 3/49 reads (6%) | catalogued as COSV57618343; called by muse, mutect2
- OTOP3 | c.963C>T p.F321= | Silent (SNP) | VAF 19/162 reads (12%) | catalogued as rs767129926, COSV60912840; called by muse, mutect2, varscan2
- PCM1 | c.837A>G p.Q279= | Silent (SNP) | VAF 11/74 reads (15%) | catalogued as rs1376624594, COSV61518303; called by muse, mutect2, varscan2
- PCMTD2 | c.261G>A p.L87= | Silent (SNP) | VAF 14/172 reads (8%) | catalogued as COSV55058925, COSV55061708; called by muse, mutect2
- SCN10A | c.3651C>T p.A1217= | Silent (SNP) | VAF 10/82 reads (12%) | catalogued as COSV71862384; called by muse, mutect2, varscan2
- STK40 | c.105C>T p.F35= | Silent (SNP) | VAF 11/98 reads (11%) | catalogued as COSV63736392; called by muse, mutect2, varscan2
- TCHH | c.2832G>A p.L944= | Silent (SNP) | VAF 19/584 reads (3%) | catalogued as COSV64276127, COSV64276830; called by muse, mutect2
- VPS13B | c.10875C>T p.F3625= | Silent (SNP) | VAF 11/51 reads (22%) | catalogued as rs772653964, COSV62152437; called by muse, mutect2, varscan2
- OBSCN | c.11660-1932A>G | Intron (SNP) | VAF 8/192 reads (4%) | catalogued as COSV99482324; called by muse, mutect2
- PCYT1B | c.*197A>G | 3'UTR (SNP) | VAF 6/58 reads (10%) | catalogued as COSV100770779; called by muse, mutect2
- RTN4 | c.3013+14994A>G | Intron (SNP) | VAF 37/141 reads (26%) | catalogued as rs369483079; called by muse, mutect2, varscan2
- SSPOP | n.14685C>T | RNA (SNP) | VAF 12/73 reads (16%) | catalogued as rs1183669225, COSV65130065; called by muse, mutect2, varscan2
